Somatic mutation profile of tumor specimen TCGA-TM-A84M-01A (aliquot TCGA-TM-A84M-01A-11D-A36O-08) from TCGA case TCGA-TM-A84M, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 40.1 years (14,660 days).
Specimen TCGA-TM-A84M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 703dc93d-baa3-4908-a252-5725bf26649d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84M-10A (Blood Derived Normal), aliquot TCGA-TM-A84M-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a5fb5a4-5cc5-4c6a-a087-43d5287c3ccb

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1380826096, COSV50546987; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 44/90 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4057G>A p.D1353N | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99285442; called by muse, mutect2, varscan2
- ADAMTS9 | c.5137C>T p.H1713Y | Missense Mutation (SNP) | VAF 52/125 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99899197; called by muse, mutect2, varscan2
- ARID1A | c.3265G>A p.A1089T | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251132; called by muse, mutect2, varscan2
- ARPIN | c.515T>C p.L172S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100673446; called by muse, mutect2, varscan2
- ATP6V1A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99850028; called by muse, mutect2, varscan2
- DMP1 | c.237T>A p.D79E | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.46); catalogued as COSV99218634; called by muse, mutect2, varscan2
- FUBP1 | c.385G>T p.E129* | Nonsense Mutation (SNP) | VAF 18/22 reads (82%) | catalogued as COSV53934628, COSV99628394; called by muse, mutect2, varscan2
- GUSB | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs747572640, CM960798, COSV59221525; called by muse, mutect2, varscan2
- KLF9 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV101009557; called by muse, mutect2, varscan2
- NEK1 | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs201793759; called by muse, mutect2, varscan2
- RSPH1 | c.840G>T p.E280D | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV99370437; called by muse, mutect2, varscan2
- SMC1A | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 61/66 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV59131948; called by muse, mutect2, varscan2
- TNN | c.3545C>T p.S1182F | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99511663; called by muse, mutect2
- USP49 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99790097; called by muse, mutect2
- ZDHHC5 | c.1768T>C p.S590P | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV99762262; called by muse, mutect2, varscan2
- CAPN9 | c.425del p.L142Rfs*4 | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | called by mutect2, pindel, varscan2
- VPS45 | c.1322G>A p.S441N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- ARHGEF37 | c.408G>A p.R136= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV100382039; called by muse, mutect2, varscan2
- ASMTL | c.522C>T p.G174= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs368676109; called by muse, mutect2
- LUC7L2 | c.174A>G p.E58= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs1336333206, COSV99692951; called by muse, mutect2, varscan2
- MUC16 | c.32403G>A p.A10801= | Silent (SNP) | VAF 95/201 reads (47%) | catalogued as rs746940715, COSV67451420; called by muse, mutect2, varscan2
- PLA2G4D | c.1614C>T p.A538= | Silent (SNP) | VAF 27/63 reads (43%) | catalogued as COSV99299515; called by muse, mutect2, varscan2
- REM2 | c.510C>A p.I170= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV99944634; called by muse, mutect2, varscan2
- RUFY1 | c.1770G>A p.R590= | Silent (SNP) | VAF 38/107 reads (36%) | catalogued as COSV100105917; called by muse, mutect2, varscan2
- FOXN4 | c.597-17C>T | Intron (SNP) | VAF 6/12 reads (50%) | catalogued as rs1335273087; called by muse, mutect2, varscan2
